Somatic mutation profile of tumor specimen TCGA-ZB-A96K-01A (aliquot TCGA-ZB-A96K-01A-11D-A428-09) from TCGA case TCGA-ZB-A96K, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 69.8 years (25,498 days).
Specimen TCGA-ZB-A96K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4591dfe0-2b7a-45e2-b354-b196a5bc20c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96K-10A (Blood Derived Normal), aliquot TCGA-ZB-A96K-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/875a1b66-ed69-4ad1-9b11-7444d34587e8

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 93/477 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- EPAS1 | c.2489C>T p.S830L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1327397090, COSV55386589; called by muse, mutect2, varscan2
- IGHV3-74 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); catalogued as rs1274442800; called by muse, mutect2
- ECHDC3 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- FAT4 | c.8264A>T p.Q2755L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- MPP5 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- REV1 | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- ZNF341 | c.2466G>T p.E822D (on ENST00000375200 / NM_001282935.1; = p.E815D on NM_032819.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); called by muse, mutect2
- CARMIL2 | c.4206T>A p.L1402= | Silent (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.390C>T p.F130= (on ENST00000427177 / NM_001113491.2; = p.F112= on NM_006640.4) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs769409038; called by muse, mutect2, varscan2
- TPM4 | c.*167G>A | 3'UTR (SNP) | VAF 9/39 reads (23%) | catalogued as rs372712176; called by muse, mutect2, varscan2
